Surgical pathology report (de-identified scan), TCGA case TCGA-CC-A9FU, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site ILSBio, specimen TCGA-CC-A9FU-01A (Primary Tumor).

[page 1 of 5]
Clinical Case Report **(For Collection of Cancerous Tissue)**

ICD O-3

Carcinoma, hepatocellular
NOS 8170/3
Site Liver C22.0
JN 4/7/14

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
		☐ Single ☒ Married	Viet nam	
Gender	Weight	☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
☐ Male ☒ Female				

HISTORY OF PRESENT ILLNESS	
Chief Complaints:	epigastric pain, fatigue, dysorexia.
Symptoms:	epigastric pain along times, fatigue and dysorexia about ago, go to hospital.
Clinical Findings:	press pain in epigastric area.
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden	

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
Not				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status
not			

OB/GYN HISTORY		
Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☒ Post-menopausal	Date of First Menses	# of Pregnancies 02
	Date of Last Menses	# of Live Births 02
	Birth Control: ☐ Condom ☐ Oral Contraceptive ☒ IUD ☐ Other:	
		Hormone Replacement Therapy: not

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis
not		

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive:		CEA	☐ Negative ☐ Positive:		
Hep B	☐ Negative ☒ Positive:		CA 15-3	☐ Negative ☐ Positive:		
Hep C	☒ Negative ☐ Positive:		CA 19-9	☐ Negative ☐ Positive:	not done	
AFP	☐ Negative ☒ Positive: 32.955 ng/mL		PSA	☐ Negative ☐ Positive:		
Other:	☐ Negative ☐ Positive:		Other:	☐ Negative ☐ Positive:		
B/T Cell Markers: not done						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound	Tumor in left Liver's lobe, 4-7,5 x 7,5 x 8 cm	
X-Ray	not done	
CT	Tumor in Segment II, d = 8 cm x 7,5 x 7,5 cm and Segment 3, 1,5 x 1,7 x 2 cm	
Endoscopy		
MRI	not done	
Biopsy	INA: H.C.C	

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Cancer of left Liver		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
not	not	
Clinical Staging		Date of Diagnosis
T _{3a} N ₀ M ₀	Stage: IIIa	

Treatment Information

SURGICAL TREATMENT		
Procedure		Date of Procedure
left hepatectomy		
Primary Tumor		
Organ	Detailed Location	Size
Liver	Left Liver	7x7,5x7,5cm
Extension of Tumor		
Local Tumor in left Liver.		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes	not	not
Dissected Lymph Nodes	not	not
Distant Metastasis		
Organ	Detailed Location	Size
not		
Surgical Staging		
T _{3a} N ₀ M ₀ Stage: IIIa		

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)					
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)	
				/ / To / /	
not				/ / To / /	
				/ / To / /	
				/ / To / /	
				/ / To / /	

[page 4 of 5]
Microscopic Description

Histological Pattern											
Cell Distribution			+	-	Structural Pattern			+	-		
Diffuse			X		Streaming				X		
Mosaic				X	Storiform				X		
Necrosis			X		Fibrosis				X		
Lymphocytic Infiltration				X	Palisading				X		
Vascular Invasion				X	Cystic Degeneration				X		
Clusterized				X	Bleeding				X		
Alveolar Formation				X	Myxoid Change				X		
Indian File				X	Psammoma/Calcification				X		

Cellular Differentiation															
Squamous		+	-	Adenomatous		+	-	Sarcomatous		+	-	Lymphomatous		+	-
Squamoid Cell			X	Glandular cell			X	Round Cell			X	Large Cell			X
Spindle Cell			X	Cell Stratification		X		Fibroblast			X	Small Cell			X
Keratin			X	Secretion			X	Osteoblast			X	RS Cell/RS Like			X
Desmosome			X	Intracyt. Vacuole		X		Lipoblast			X	Inflam. Cell			X
Pearl			X	Gland formation			X	Myoblast			X	Plasma Cell			X

Cellular Differentiation:				Well	X	Moderate	Poor
---------------------------	--	--	--	------	---	----------	------

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis			X	
Hyperchromatism			X	
Nucleolar Prominent		X		
Multinucleated Giant Cell		X		
Mitotic Activity			X	
Nuclear Grade:			X	

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive	/ not done	
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other: HPV B	☐ Negative ☒ Positive		
Other: AFP	☐ Negative ☒ Positive	32.955.05 ng/ml	

Final Pathology Report

Histological Diagnosis: Moderately differentiated Hepatocellular
Carcinoma Grade: 2/

Comments:

Principal Investigator

Pathologist

Date

[page 5 of 5]
Consolidated Pathology Diagnosis

Histological Pattern											
Cell Distribution			+ -		Structural Pattern			+ -			
Diffuse			☒ ☒		Streaming						
Mosaic			☒ ☐		Storiform						
Necrosis			☐ ☒		Fibrosis						
Lymphocytic Infiltration			☒ ☐		Palisading						
Vascular Invasion			☐ ☒		Cystic Degeneration						
Clusterized			☒ ☐		Bleeding						
Alveolar Formation			☐ ☒		Myxoid Change						
Indian File			☐ ☒		Psammoma/Calcification						

Cellular Differentiation															
Squamous		+ -		Adenomatous		+ -		Sarcomatous		+ -		Lymphomatous		+ -	
Squamoid Cell				Glandular cell		☒ ☐		Round Cell				Large Cell			
Spindle Cell				Cell Stratification		☒ ☐		Fibroblast				Small Cell			
Keratin				Secretion		☒ ☐		Osteoblast				RS Cell/RS Like			
Desmosome				Intracyt. Vacuole		☒ ☐		Lipoblast				Inflam. Cell			
Pearl				Gland formation		☒ ☐		Myoblast				Plasma Cell			

Cellular Differentiation:					☐ Well ☒ Moderate ☐ Poor	
---------------------------	--	--	--	--	--	--

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis			☒	
Hyperchromatism			☒	
Nucleolar Prominent			☒	
Multinucleated Giant Cell			☒	
Mitotic Activity			☒	
Nuclear Grade:				

Final Pathology Report

Histological Diagnosis: Hepatocellular carcinoma **Grade:** 2
Tagliocellular type

Comments:

Director, Research Pathology

Date

INTEGRATED REPORT OF FINDINGS BY COLLABORATORS AND

PATHOLOGISTS - FOR

hw 1/3/14 12/13/13

Source: NCI Genomic Data Commons file 89a926d2-afca-4269-9b42-44be4a717c67 (TCGA-CC-A9FU.95F22F75-89A6-4B67-BDF2-A357825453EF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).